Somatic mutation profile of tumor specimen TCGA-AY-6196-01A (aliquot TCGA-AY-6196-01A-11D-1719-10) from TCGA case TCGA-AY-6196, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 47.4 years (17,311 days).
Specimen TCGA-AY-6196-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34f2f5ae-c84b-4764-9ff7-466cf368841e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-6196-10A (Blood Derived Normal), aliquot TCGA-AY-6196-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c4b79ea-7e9e-427d-aed9-36aa808e9d59

The open-access MAF lists 246 somatic variants for this specimen: 190 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 49, Nonsense Mutation 12, Splice Site 11, Frame Shift Del 7, Intron 5, Frame Shift Ins 3, 3'UTR 2, Splice Region 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 48/105 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WAS | c.777+1G>A p.X259_splice | Splice Site (SNP) | VAF 39/73 reads (53%) | catalogued as rs1057517845, CS020216, CS961713, COSV64997624; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1508A>C p.E503A | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV66069542; called by muse, mutect2, varscan2
- ABCA4 | c.2951C>A p.S984Y | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV64676680; called by muse, mutect2, varscan2
- AC006059.2 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100046072, COSV59608880; called by muse, mutect2, varscan2
- ACP7 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs764013644, COSV58700532; called by muse, mutect2, varscan2
- ACSM2A | c.1382G>A p.R461Q (on ENST00000219054; = p.R382Q on NM_001308169.2) | Missense Mutation (SNP) | VAF 117/390 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747273688, COSV54589872; called by muse, mutect2, varscan2
- ADAM12 | c.775A>T p.I259F | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV64112660; called by muse, mutect2
- ADAMTS7 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV66309018; called by muse, mutect2
- ADAMTSL4 | c.1984G>C p.G662R | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV55005278; called by muse, mutect2
- ADAP2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.053); catalogued as COSV58297212; called by muse, mutect2, varscan2
- ADGRE3 | c.1824A>T p.Q608H | Missense Mutation (SNP) | VAF 58/465 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV53733884; called by muse, mutect2, varscan2
- ADGRG2 | c.2863G>C p.G955R (on ENST00000379869 / NM_001079858.3; = p.G952R on NM_005756.4) | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV61340723; called by muse, mutect2, varscan2
- AMPD1 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as COSV62415806, COSV62418126; called by muse, mutect2, varscan2
- ANKRD55 | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61949742; called by muse, mutect2, varscan2
- ANXA4 | c.477+1G>A p.X159_splice | Splice Site (SNP) | VAF 44/352 reads (13%) | catalogued as COSV67849381; called by muse, mutect2, varscan2
- ARAP2 | c.3416T>C p.V1139A | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58290882; called by muse, mutect2, varscan2
- ARID4B | c.1430A>C p.E477A | Missense Mutation (SNP) | VAF 44/423 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV51606223, COSV51609300; called by muse, mutect2, varscan2
- ASPH | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.005); catalogued as rs1370265187, COSV62860890; called by muse, mutect2
- ASPN | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 33/267 reads (12%) | catalogued as rs201600758, COSV65016541; called by muse, mutect2, varscan2
- ATXN7L2 | c.700+1G>A p.X234_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as rs1288347363, COSV63992122; called by muse, mutect2, varscan2
- C10orf99 | c.69A>G p.E23= | Splice Region (SNP) | VAF 39/167 reads (23%) | catalogued as rs1027139480, COSV100929359, COSV64532198; called by muse, mutect2, varscan2
- CCDC171 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV52649984; called by muse, mutect2, varscan2
- CCDC197 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100113675; called by muse, mutect2, varscan2
- CCNDBP1 | c.861-1G>C p.X287_splice | Splice Site (SNP) | VAF 58/392 reads (15%) | catalogued as COSV55747724; called by muse, mutect2, varscan2
- CDC25B | c.662G>T p.R221M (on ENST00000245960 / NM_021873.3; = p.R207M on NM_004358.4) | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55658973; called by muse, mutect2, varscan2
- CDH10 | c.1880T>C p.I627T | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1347385291, COSV100052001; called by muse, mutect2, varscan2
- CEP170 | c.1968G>C p.E656D | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV60513094; called by muse, mutect2
- COL4A4 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV61635475; called by muse, varscan2
- CPNE2 | c.1202G>A p.C401Y | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51964356; called by muse, mutect2, varscan2
- CRISP3 | c.246A>T p.R82S (on ENST00000371159 / NM_001368123.1; = p.R64S on NM_006061.4) | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV53822449; called by muse, mutect2, varscan2
- CRYBG1 | c.4600G>T p.D1534Y | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64813998; called by muse, mutect2, varscan2
- CSMD2 | c.9949G>C p.E3317Q | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as COSV53948985; called by muse, mutect2, varscan2
- CYP24A1 | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV53773006, COSV99398419; called by muse, mutect2
- CYP27C1 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV58867883; called by muse, mutect2, varscan2
- CYP7A1 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV56965238; called by muse, mutect2, varscan2
- DBR1 | c.1056G>C p.K352N | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV53430871; called by muse, mutect2
- DEPDC5 | c.3122C>A p.T1041N (on ENST00000400246; = p.T1110N on NM_014662.5) | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs926750227, COSV99835763; called by muse, mutect2, varscan2
- DFFA | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV65478074; called by muse, mutect2, varscan2
- DISP3 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 49/103 reads (48%) | catalogued as COSV53825250, COSV99609133; called by muse, varscan2
- DNAJA2 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 31/290 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1370357490, COSV57695341; called by muse, mutect2, varscan2
- DNTTIP1 | c.951G>C p.E317D | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.986); catalogued as COSV54755474; called by muse, mutect2
- DOCK8 | c.6013A>G p.K2005E | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as COSV66622984; called by muse, mutect2, varscan2
- DPYD | c.2981G>A p.S994N | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV64610806; called by muse, mutect2, varscan2
- DRC7 | c.1120A>C p.M374L | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV61057370; called by muse, mutect2, varscan2
- DTX3 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as rs752141567, COSV54089722; called by muse, mutect2, varscan2
- EMILIN2 | c.1576G>A p.G526R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs753787308, COSV54426516; called by muse, mutect2, varscan2
- FCN2 | c.779T>C p.M260T | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52478295; called by muse, mutect2, varscan2
- FER1L6 | c.627A>C p.K209N | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV67552150; called by muse, mutect2, varscan2
- FGFR2 | c.1491G>A p.M497I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV60656292; called by muse, mutect2, varscan2
- FGFR2 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV60656314; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 134/416 reads (32%) | catalogued as rs41289190, COSV58563360; called by muse, mutect2, varscan2
- FRMD1 | c.461+1G>T p.X154_splice | Splice Site (SNP) | VAF 28/128 reads (22%) | catalogued as COSV51964385, COSV99349376; called by muse, mutect2, varscan2
- FSD2 | c.1699C>T p.R567C | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs752837620, COSV58012182; called by muse, mutect2, varscan2
- GAA | c.1390A>T p.R464W | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56411177; called by muse, mutect2, varscan2
- GALNTL6 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189797609, COSV72492885; called by muse, mutect2, varscan2
- GDF10 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); catalogued as rs782809728; called by muse, mutect2, varscan2
- GLI3 | c.1999C>T p.R667* | Nonsense Mutation (SNP) | VAF 54/237 reads (23%) | catalogued as rs781422192, HM971694, COSV67885657; called by muse, mutect2, varscan2
- GLP1R | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as COSV64716230; called by muse, mutect2, varscan2
- GLP1R | c.610A>C p.M204L | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV64716233; called by muse, mutect2, varscan2
- GPR139 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV58504505; called by muse, mutect2, varscan2
- GPT | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.467); catalogued as COSV52954412, COSV99477349; called by muse, mutect2, varscan2
- HECTD4 | c.11327C>T p.A3776V | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV101107872; called by muse, mutect2
- HGF | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99737540; called by muse, mutect2
- HSPA2 | c.1793A>T p.K598M | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as rs142308248; called by muse, mutect2, varscan2
- IGKV1-33 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.363); catalogued as rs759540355, COSV101522093; called by muse, mutect2, varscan2
- ILF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 67/256 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV62627950; called by muse, mutect2, varscan2
- INSM2 | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99355245; called by muse, mutect2
- IPO5 | c.908A>G p.Q303R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as rs1241757671, COSV55158479; called by muse, mutect2, varscan2
- IRAG2 | c.4187T>C p.L1396P (on ENST00000636465; = p.L441P on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV57235693; called by muse, mutect2, varscan2
- JAM2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57259961; called by muse, mutect2, varscan2
- JCAD | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); catalogued as rs746067055, COSV64761252; called by muse, mutect2, varscan2
- KIF27 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 42/298 reads (14%) | catalogued as COSV99927093; called by muse, mutect2, varscan2
- KIFC3 | c.1218+2T>A p.X406_splice | Splice Site (SNP) | VAF 15/110 reads (14%) | catalogued as COSV65552671; called by muse, mutect2
- KMT2E | c.3832G>C p.D1278H | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1173740073, COSV57578268; called by muse, mutect2, varscan2
- LAMP2 | c.40C>A p.L14I | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV52354616; called by muse, mutect2, varscan2
- LCA5L | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 78/363 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV55746917; called by muse, mutect2, varscan2
- LGSN | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372668010; called by muse, mutect2, varscan2
- LIMD1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV56269752; called by muse, mutect2
- LONRF1 | c.2093T>A p.L698* | Nonsense Mutation (SNP) | VAF 10/97 reads (10%) | catalogued as COSV101238237; called by muse, mutect2, varscan2
- LPAR5 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV61693018; called by muse, mutect2, varscan2
- LRRC42 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV59961675; called by muse, mutect2, varscan2
- MACC1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs376402233, COSV60543185; called by muse, mutect2, varscan2
- MC1R | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as COSV59626603, COSV59626814; called by muse, mutect2, varscan2
- MIPOL1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV59391312; called by muse, varscan2
- MRPL47 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV52020620, COSV52021532; called by muse, mutect2, varscan2
- MST1R | c.3296G>C p.G1099A | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56572549; called by muse, mutect2, varscan2
- MUC16 | c.5420G>A p.G1807E | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1429084800, COSV67485461; called by muse, mutect2, varscan2
- MYCBP2 | c.111C>A p.D37E (on ENST00000357337; = p.D75E on NM_015057.5) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62034765; called by muse, mutect2, varscan2
- NAV2 | c.2245A>G p.T749A (on ENST00000396087 / NM_001244963.2; = p.T726A on NM_145117.5) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62331548; called by muse, mutect2, varscan2
- NCEH1 | c.173C>A p.S58Y (on ENST00000538775; = p.S26Y on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/326 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV56437461; called by muse, mutect2, varscan2
- NEDD4 | c.492C>A p.S164R | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59065546; called by muse, mutect2, varscan2
- NNT | c.2414T>G p.I805S | Missense Mutation (SNP) | VAF 62/583 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV52922687, COSV99239133; called by muse, mutect2, varscan2
- NPHP1 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 66/396 reads (17%) | catalogued as COSV57210939; called by muse, mutect2, varscan2
- ONECUT2 | c.1203G>C p.Q401H | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101529801; called by muse, mutect2, varscan2
- OR4A5 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV60523983; called by muse, mutect2, varscan2
- OR5AC2 | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62280007; called by muse, mutect2, varscan2
- OSBP | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55665038; called by muse, mutect2, varscan2
- PALMD | c.1456T>C p.S486P | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54166247; called by muse, mutect2, varscan2
- PARP1 | c.1508T>G p.L503R | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV64691789; called by muse, mutect2, varscan2
- PCDHA7 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65346602; called by muse, mutect2
- PCDHB13 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); catalogued as rs1554287752, COSV53399800; called by muse, mutect2, varscan2
- PDE3A | c.1847-1G>A p.X616_splice | Splice Site (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100762937, COSV62980609; called by muse, mutect2, varscan2
- PDZRN3 | c.3099C>G p.I1033M | Missense Mutation (SNP) | VAF 50/552 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV55212351; called by muse, mutect2
- PGGHG | c.1106A>T p.H369L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67141425; called by muse, mutect2, varscan2
- PIKFYVE | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 97/558 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV52237610; called by muse, mutect2, varscan2
- PKD1L1 | c.7504G>A p.V2502I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs371450996, COSV51842331; called by muse, mutect2, varscan2
- PLAAT4 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs371930466; called by muse, mutect2, varscan2
- PLCE1 | c.4447A>G p.I1483V | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs886047503, COSV53366485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3B | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99943548; called by muse, mutect2, varscan2
- PPM1J | c.671A>C p.K224T | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58552695; called by muse, mutect2, varscan2
- PPM1L | c.956A>C p.E319A | Missense Mutation (SNP) | VAF 39/215 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV55569101; called by muse, mutect2, varscan2
- PPP2R3A | c.2788+2T>A p.X930_splice | Splice Site (SNP) | VAF 66/303 reads (22%) | catalogued as COSV53869388; called by muse, mutect2, varscan2
- PRAMEF5 | c.1339C>A p.H447N | Missense Mutation (SNP) | VAF 112/440 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100871212; called by muse, varscan2
- PRAMEF5 | c.1384G>T p.G462C | Missense Mutation (SNP) | VAF 86/454 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871302; called by muse, varscan2
- PTPRZ1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 100/638 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as rs1385479485, COSV66443655; called by muse, mutect2, varscan2
- PUS10 | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.194); catalogued as COSV57454358; called by muse, mutect2, varscan2
- RABGAP1 | c.2520G>A p.R840= | Splice Region (SNP) | VAF 27/175 reads (15%) | catalogued as COSV65380799; called by muse, mutect2, varscan2
- RAD54L2 | c.2135A>G p.Y712C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56580916; called by muse, mutect2, varscan2
- RADIL | c.1817C>G p.P606R | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68202978, COSV68204062; called by muse, mutect2
- RBBP8NL | c.1826G>C p.G609A | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as COSV53350471; called by muse, mutect2
- REM2 | c.422G>T p.S141I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV57465965; called by muse, mutect2, varscan2
- RGS12 | c.1643G>A p.C548Y | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs1198839786, COSV100375875; called by muse, mutect2
- RHBDD1 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 106/734 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV58130596; called by muse, mutect2, varscan2
- RIF1 | c.3227G>A p.R1076Q | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54622313; called by muse, mutect2, varscan2
- RIPOR3 | c.2312G>T p.R771M | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50399254; called by muse, mutect2
- RSL1D1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1187172359, COSV63078339; called by muse, mutect2, varscan2
- RUNX1T1 | c.1176G>C p.W392C (on ENST00000265814 / NM_001198628.1; = p.W365C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56159706; called by muse, mutect2
- RYR1 | c.11233G>C p.E3745Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as COSV100616147; called by muse, mutect2
- S100PBP | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as rs749717746, COSV63140487; called by muse, mutect2, varscan2
- SATB2 | c.561C>G p.N187K | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99611612; called by muse, mutect2
- SCUBE1 | c.2429A>T p.E810V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100683432; called by muse, mutect2
- SEMA3E | c.1456A>T p.K486* | Nonsense Mutation (SNP) | VAF 20/224 reads (9%) | catalogued as COSV57104238; called by muse, mutect2
- SEZ6L | c.2366G>T p.W789L | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV50678363; called by muse, mutect2, varscan2
- SGSM1 | c.575G>A p.W192* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101240886; called by muse, mutect2, varscan2
- SH2B3 | c.1507T>A p.S503T | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV57985725; called by muse, mutect2, varscan2
- SLC22A10 | c.1070+1G>T p.X357_splice | Splice Site (SNP) | VAF 17/115 reads (15%) | catalogued as COSV60423115; called by muse, mutect2, varscan2
- SLC25A42 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV59381410; called by muse, mutect2, varscan2
- SLC25A44 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63962236; called by muse, mutect2, varscan2
- SLIT1 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.508); catalogued as rs774613268, COSV56596755; called by muse, mutect2, varscan2
- SNX1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs111801077, COSV56039530; called by muse, mutect2, varscan2
- SOGA3 | c.1783G>T p.E595* | Nonsense Mutation (SNP) | VAF 22/252 reads (9%) | catalogued as COSV64105589, COSV64108151; called by muse, mutect2
- SOX11 | c.407A>C p.Q136P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV100430686, COSV100431261; called by muse, mutect2
- SPACA1 | c.671C>A p.T224N | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV52759382; called by muse, mutect2, varscan2
- SPATA31E1 | c.3452C>T p.S1151F | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV100350647; called by muse, mutect2
- SPX | c.67A>G p.N23D | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV57021544; called by muse, mutect2, varscan2
- SRCAP | c.5633dup p.P1879Tfs*21 | Frame Shift Ins (INS) | VAF 36/148 reads (24%) | catalogued as rs748467821; called by mutect2, varscan2
- ST6GAL1 | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as COSV51467110, COSV51473610, COSV99398101; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2868G>T p.Q956H | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1472515055, COSV59136078, COSV59137471; called by muse, mutect2, varscan2
- SULF1 | c.2583C>G p.H861Q | Missense Mutation (SNP) | VAF 50/451 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV52690376, COSV99483248; called by muse, mutect2, varscan2
- SVEP1 | c.6152A>G p.Y2051C | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52836173; called by muse, mutect2
- SYNE4 | c.94A>C p.T32P | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV53325545; called by muse, mutect2
- TARS1 | c.454-2A>T p.X152_splice | Splice Site (SNP) | VAF 14/188 reads (7%) | catalogued as COSV99466104; called by muse, mutect2
- TJP1 | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 280/583 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV62045259; called by muse, mutect2, varscan2
- TJP1 | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 279/576 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV62045267; called by muse, mutect2, varscan2
- TMEM109 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV50017887; called by muse, mutect2, varscan2
- TMEM132D | c.3157G>A p.V1053I | Missense Mutation (SNP) | VAF 171/325 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750913130, COSV67160883; called by muse, mutect2, varscan2
- TMOD1 | c.460T>C p.S154P | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV99403931; called by muse, mutect2
- TOR1AIP2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV62625763; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2249G>T p.G750V | Missense Mutation (SNP) | VAF 43/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61458027; called by muse, mutect2, varscan2
- TRPM6 | c.3164T>A p.F1055Y | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62520079; called by muse, mutect2, varscan2
- TSSK1B | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV66815894; called by muse, mutect2, varscan2
- TTF2 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 140/421 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs776227653, COSV65633427; called by muse, mutect2, varscan2
- TTLL4 | c.3227A>C p.H1076P | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51438728; called by muse, mutect2, varscan2
- TTN | c.59973C>G p.F19991L (on ENST00000591111; = p.F12567L on NM_003319.4) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | PolyPhen probably damaging (0.987); catalogued as COSV60271792, COSV60314619; called by muse, mutect2, varscan2
- TTN | c.39350G>A p.R13117Q (on ENST00000591111; = p.R5693Q on NM_003319.4) | Missense Mutation (SNP) | VAF 30/186 reads (16%) | PolyPhen possibly damaging (0.479); catalogued as rs770389312, COSV60271834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH1 | c.1219G>C p.A407P | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV100002192; called by muse, mutect2
- TUBA1C | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV56511511; called by muse, mutect2, varscan2
- UBE4B | c.2856T>G p.F952L (on ENST00000343090 / NM_001105562.3; = p.F823L on NM_006048.5) | Missense Mutation (SNP) | VAF 122/422 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1437013074, COSV53540071; called by muse, mutect2, varscan2
- USH2A | c.9710G>T p.C3237F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201909450, COSV56418732; called by muse, mutect2, varscan2
- USP32 | c.4213A>T p.S1405C | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV56275198; called by muse, mutect2, varscan2
- WDR7 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54360885; called by muse, varscan2
- WDR90 | c.3526G>T p.A1176S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53474026; called by muse, mutect2
- ZNF107 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV100788236, COSV61331187; called by muse, varscan2
- ZNF141 | c.207del p.I70Sfs*2 | Frame Shift Del (DEL) | VAF 28/187 reads (15%) | catalogued as COSV53659646; called by mutect2, pindel, varscan2
- ZNF606 | c.1634G>A p.C545Y | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58707647; called by muse, mutect2, varscan2
- ZNF804B | c.1768G>T p.D590Y | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV60847693; called by muse, mutect2, varscan2
- ZNF823 | c.395G>C p.G132A (on ENST00000341191 / NM_001297610.2; = p.G88A on NM_017507.2) | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV57875609; called by muse, mutect2, varscan2
- DIP2B | c.2935_2960del p.I979Afs*17 | Frame Shift Del (DEL) | VAF 34/277 reads (12%) | called by mutect2, pindel
- GABRA1 | c.1203_1213del p.P402Tfs*9 | Frame Shift Del (DEL) | VAF 56/207 reads (27%) | called by mutect2, pindel, varscan2
- GSAP | c.1847_1869del p.D616Gfs*8 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel
- IGKV1D-33 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 39/535 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- LRIG1 | c.2604_2614del p.H868Qfs*44 | Frame Shift Del (DEL) | VAF 20/113 reads (18%) | called by mutect2, pindel, varscan2
- MAPK1IP1L | c.423_441del p.L142Cfs*134 | Frame Shift Del (DEL) | VAF 25/170 reads (15%) | called by mutect2, pindel, varscan2
- MEI1 | c.423+1_423+5del p.X141_splice | Splice Site (DEL) | VAF 12/125 reads (10%) | called by mutect2, pindel
- PPP1R12B | c.1048_1068del p.M350_E356del | In Frame Del (DEL) | VAF 21/143 reads (15%) | called by mutect2, pindel, varscan2
- PSMD1 | c.1805dup p.L603Afs*7 | Frame Shift Ins (INS) | VAF 42/255 reads (16%) | called by mutect2, pindel, varscan2
- PTPN5 | c.165_166dup p.M56Rfs*70 | Frame Shift Ins (INS) | VAF 26/120 reads (22%) | called by mutect2, varscan2
- TUT7 | c.80_126del p.G27Afs*4 | Frame Shift Del (DEL) | VAF 51/622 reads (8%) | called by mutect2, pindel
- AC006059.2 | c.1545A>T p.S515= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV59608890; called by muse, mutect2, varscan2
- ACAN | c.6231G>A p.G2077= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV61367323; called by muse, mutect2, varscan2
- ADAM10 | c.2166G>A p.R722= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV53053967; called by muse, mutect2, varscan2
- ARID1A | c.6612C>G p.A2204= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV61385953; called by muse, mutect2, varscan2
- ARMC4 | c.2934C>T p.N978= | Silent (SNP) | VAF 89/287 reads (31%) | catalogued as rs139934178; ClinVar: likely benign; called by muse, mutect2, varscan2
- BRCA2 | c.4179G>A p.A1393= | Silent (SNP) | VAF 48/197 reads (24%) | catalogued as rs770531115, COSV66448433; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- CCDC73 | c.1716C>T p.N572= | Silent (SNP) | VAF 57/298 reads (19%) | catalogued as rs773064565, COSV58794671; called by muse, mutect2, varscan2
- CCN3 | c.414T>A p.I138= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as COSV52385018; called by muse, mutect2
- CNKSR3 | c.1626C>A p.L542= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV70481457; called by muse, mutect2, varscan2
- CNOT3 | c.807C>G p.P269= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV55367086; called by muse, mutect2, varscan2
- COL14A1 | c.4872C>T p.C1624= | Silent (SNP) | VAF 50/403 reads (12%) | catalogued as rs150301131; called by muse, mutect2, varscan2
- DNAH7 | c.3282T>A p.P1094= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV56780116; called by muse, mutect2, varscan2
- DNAH8 | c.4971T>C p.D1657= | Silent (SNP) | VAF 40/269 reads (15%) | catalogued as COSV59472389; called by muse, mutect2, varscan2
- FAM237A | c.192C>T p.R64= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as rs551796647, COSV101405586; called by muse, mutect2, varscan2
- FBXW7 | c.1848A>T p.T616= (on ENST00000281708 / NM_001349798.2; = p.T536= on NM_018315.5) | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV55944936; called by muse, mutect2, varscan2
- GALNT2 | c.270G>A p.T90= | Silent (SNP) | VAF 34/261 reads (13%) | catalogued as rs746006005, COSV64197224; called by muse, mutect2, varscan2
- GATA2 | c.1185T>G p.T395= | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV62006185; called by muse, mutect2, varscan2
- GPR15 | c.489G>T p.L163= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV99423824; called by muse, mutect2, varscan2
- GRM8 | c.471C>T p.S157= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as rs146190169; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH5 | c.2103C>T p.P701= | Silent (SNP) | VAF 58/195 reads (30%) | catalogued as rs112731796, COSV59770233; ClinVar: likely benign; called by muse, mutect2, varscan2
- LARP7 | c.1401C>A p.G467= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as COSV60521065, COSV60522036; called by muse, mutect2
- LMF1 | c.975C>T p.D325= | Silent (SNP) | VAF 44/198 reads (22%) | catalogued as rs780310924, COSV51901205; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEB1 | c.777G>A p.Q259= | Silent (SNP) | VAF 136/201 reads (68%) | catalogued as COSV66776398; called by muse, mutect2, varscan2
- MAP4K4 | c.1539G>A p.Q513= | Silent (SNP) | VAF 51/328 reads (16%) | catalogued as COSV56338370; called by muse, mutect2, varscan2
- MGAT1 | c.681G>A p.P227= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs748284811, COSV57135158; called by muse, mutect2, varscan2
- MTUS2 | c.1062G>A p.P354= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs200333897, COSV70920246; called by muse, mutect2, varscan2
- MUS81 | c.1035C>T p.I345= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as rs112360416; called by muse, mutect2, varscan2
- MYBPC3 | c.2235T>C p.D745= | Silent (SNP) | VAF 30/279 reads (11%) | catalogued as COSV57032393; called by muse, mutect2, varscan2
- MYO1D | c.507C>T p.N169= | Silent (SNP) | VAF 34/205 reads (17%) | catalogued as COSV59021227; called by muse, mutect2, varscan2
- NKAP | c.576G>A p.R192= | Silent (SNP) | VAF 139/524 reads (27%) | catalogued as COSV101004252; called by muse, mutect2, varscan2
- NLRP7 | c.1284C>T p.S428= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV60173605; called by muse, mutect2
- NRXN1 | c.660C>T p.G220= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as COSV68002608, COSV68038322; called by muse, mutect2, varscan2
- OBSCN | c.12657G>C p.L4219= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV52814323; called by muse, mutect2
- OGDH | c.2313G>T p.R771= | Silent (SNP) | VAF 19/157 reads (12%) | catalogued as COSV56048808, COSV56055389; called by muse, mutect2, varscan2
- OR10V1 | c.345G>A p.L115= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- PLXNB1 | c.5784C>G p.T1928= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV56493220; called by muse, mutect2, varscan2
- PTK2 | c.2061A>G p.Q687= | Silent (SNP) | VAF 39/187 reads (21%) | catalogued as COSV61790585; called by muse, mutect2, varscan2
- RBPJL | c.468G>T p.L156= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as COSV59215371; called by muse, mutect2
- RYR2 | c.8184C>A p.S2728= | Silent (SNP) | VAF 90/676 reads (13%) | catalogued as COSV100771373; called by muse, mutect2, varscan2
- SALL1 | c.3750C>T p.N1250= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as rs142653419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERTAD1 | c.132C>A p.S44= | Silent (SNP) | VAF 18/615 reads (3%) | called by muse, mutect2
- SLITRK4 | c.1314G>A p.E438= | Silent (SNP) | VAF 28/135 reads (21%) | catalogued as rs1556426987, COSV62024555, COSV62025705; called by muse, mutect2, varscan2
- TFEB | c.498T>C p.R166= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV57826463; called by muse, mutect2, varscan2
- TRIM46 | c.1692G>A p.L564= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV58113050, COSV58117743; called by muse, mutect2
- UNC79 | c.3429A>C p.T1143= (on ENST00000393151 / NM_001346218.2; = p.T966= on NM_020818.5) | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as COSV56405095; called by muse, mutect2, varscan2
- USP11 | c.1044C>T p.F348= (on ENST00000218348; = p.F305= on NM_001371072.1) | Silent (SNP) | VAF 192/282 reads (68%) | catalogued as COSV54475402; called by muse, mutect2, varscan2
- ZBTB48 | c.1233C>G p.T411= | Silent (SNP) | VAF 43/311 reads (14%) | catalogued as COSV66554095; called by muse, mutect2, varscan2
- ZNF135 | c.1110C>A p.T370= (on ENST00000313434 / NM_001289401.2; = p.T382= on NM_003436.4) | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as rs1396071701, COSV57884933; called by muse, mutect2, varscan2
- ZNF521 | c.3432C>T p.N1144= | Silent (SNP) | VAF 139/519 reads (27%) | catalogued as rs1011241462, COSV64130709; called by muse, mutect2, varscan2
- CCDC33 | c.2139+45A>T | Intron (SNP) | VAF 12/61 reads (20%) | catalogued as COSV51434284; called by muse, mutect2, varscan2
- CDK20 | c.76-39C>T | Intron (SNP) | VAF 20/71 reads (28%) | catalogued as COSV57483921; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2486G>A | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as rs549699042, COSV56000792; called by muse, mutect2, varscan2
- CRYGC | c.*2A>G | 3'UTR (SNP) | VAF 20/147 reads (14%) | catalogued as COSV52206323; called by muse, mutect2
- DNMT3B | c.*2_*13del | 3'UTR (DEL) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- PRKG1 | c.478+146257C>G | Intron (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100908768; called by muse, mutect2, varscan2
- SLIT2 | c.1463-578C>T | Intron (SNP) | VAF 15/93 reads (16%) | catalogued as rs1261393936, COSV56588435; called by muse, mutect2, varscan2
